Gene-level copy-number profile of tumor specimen MP2PRT-PAUFKI-TMP1-A from MP2PRT case MP2PRT-PAUFKI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,380 days).
Specimen MP2PRT-PAUFKI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5813c0f4-c0f4-4bec-82df-06e8b39f1124.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUFKI-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/82ad0b6d-1b23-44f6-ad8d-3fd5821c37df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 741; copy number 2: 40,701; copy number 3: 16,558; copy number 4: 593; copy number 5: 297; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.
- chr22:18,846,811–18,861,049, 2 genes (within-gene range 0–2): AC008132.1, BCRP7.
- chr22:22,734,607–22,739,187, 2 genes (within-gene range 0–2): IGLV2-18, IGLV3-17.
- chr22:22,755,554–22,755,797, 1 gene (within-gene range 0–2): IGLV3-15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 302 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,929,232, 7 genes, copy number 5: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr9:64,621,560–64,765,535, 5 genes, copy number 6: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr21:9,053,122–9,059,060, 1 gene, copy number 5: CR392039.4.
- chr21:22,882,582–22,884,000, 1 gene, copy number 5: AP000949.1.
- chr21:36,698,773–46,570,015, 288 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 229. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
